Somatic mutation profile of tumor specimen TCGA-QR-A6GY-01A (aliquot TCGA-QR-A6GY-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 37.3 years (13,612 days).
Specimen TCGA-QR-A6GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69f6f4df-9b28-4bcf-b3b8-2098f59b91b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GY-10A (Blood Derived Normal), aliquot TCGA-QR-A6GY-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7cd3d94-fb71-4ccb-b8f4-62d50c1a4fd5

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO3 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV56809756; called by muse, mutect2, varscan2
- PRPF8 | c.6796C>T p.R2266C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs777765806, COSV56772795; called by muse, mutect2
- VAV1 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs764184305; called by muse, mutect2, varscan2
- VCAN | c.6343_6345del p.T2115del | In Frame Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs1485795393; called by pindel, varscan2
- AP4E1 | c.2330A>G p.E777G | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARHGEF39 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ENOX2 | c.740A>C p.Y247S (on ENST00000338144 / NM_001382520.1; = p.Y218S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- LPAR4 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- NOL4 | c.1764C>G p.S588R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.277); called by muse, mutect2
- AK9 | c.5283T>C p.C1761= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- CDH5 | c.2308C>T p.L770= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- CYP2B6 | c.960T>C p.V320= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs775106445; called by muse, mutect2
- IGHV1-45 | c.237C>T p.Y79= | Silent (SNP) | VAF 74/189 reads (39%) | catalogued as rs191537967; called by muse, mutect2, varscan2
- OR51V1 | c.195C>T p.F65= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- SSX6P | n.366G>T | RNA (SNP) | VAF 100/280 reads (36%) | called by muse, mutect2, varscan2
